Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70P-01A (Primary Tumor).

Surgical Pathology	Final Results
Surgical Pathology	Final

CASE NUMBER:
DIAGNOSIS:
SPECIMEN LABELED "INTERAORTOCAVAL TUMOR" (EXCISION); PHEOCHROMOCYTOMA (5.5 X 4 X 3.5 CM), INKED SURGICAL MARGINS FREE OF TUMOR. ONE LYMPH NODE, NO TUMOR SEEN, SEE NOTE.
NOTE: NO ADRENAL TISSUE IDENTIFIED.

CLINICAL INFORMATION: HISTORY: RIGHT RETROPERITONEAL MASS EXAM IS RELATED TO ORDERING
PROTOCOL ORDERING PROTOCOL:

PROCEDURE: PREOP DX: #RIGHT RETROPERITONEAL MASS POSTOP DX: SAME OPERATIVE FINDINGS:
AS ABOVE

GROSS DESCRIPTION:
RECEIVED FRESH WEIGHING 39.1 GRAMS AND MEASURING 5.5 X 4 X 3.5 CM. AND LABELED
"INTERAORTOCAVAL TUMOR" IS A SINGLE PIECE OF RED/PURPLE, SOFT TISSUE, WITH SMOOTH
SURFACE AND SOMEWHAT SOFT AND WITH DIMENSIONS AS DESCRIBED. THE SPECIMEN IS INKED
BLACK AND OPENED TO REVEAL A HOMOGENEOUS, SOFT, DARK PURPLE CUT SURFACE. 2 X 1 X 0.4 CM.
FROM THE CENTRAL PORTION PROCURED FOR UOB. IN SURGICAL PATHOLOGY, THE SPECIMEN IS
GENEROUSLY SAMPLED AND REPRESENTATIVE SECTION SUBMITTED IN WHITE CASSETTES

Source: NCI Genomic Data Commons file f165df07-71a6-4041-8053-d59fec6d16e9 (TCGA-QR-A70P.47168347-3991-44BB-A3A5-4A1562E5AEF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).